Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4688, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4688-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1:

RIB, 9TH LEFT, EXCISION –
BENIGN PORTION OF BONE.

PART 2:

KIDNEY, OMENTUM AND COLON, LEFT, RADICAL NEPHRECTOMY –

- A. HIGH GRADE PLEOMORPHIC MALIGNANT TUMOR WITH EXTENSIVE SARCOMATOID DIFFERENTIATION, FAVOR SARCOMATOID RENAL CELL CARCINOMA.
- B. THE SARCOMATOID TUMOR ARISES ADJACENT AND FROM A FOCUS OF CHROMOPHOBE RENAL CELL CARCINOMA. (21 CM) (see comment).
- C. THERE IS EXTENSIVE NECROSIS.
- D. THE NEOPLASM INVOLVES THE PERINEPHRIC ADIPOSE TISSUE, OMENTUM AND COLON.
- E. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ONE COLON RESECTION MARGIN IS POSITIVE FOR NEOPLASM; REMAINDER OF SURGICAL MARGINS ARE FREE OF NEOPLASM.
- G. SARCOMATOID TUMOR IS PRESENT IN THE SOFT TISSUE SURROUNDING THE VASCULAR MARGIN.
- H. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION.
- I. TNM STAGE: PT4 NX M1.

PART 3:

SPLEEN, SPLENECTOMY –

- A. METASTATIC RENAL CELL CARCINOMA WITH EXTENSIVE SARCOMATOID DIFFERENTIATION.
- B. THE NEOPLASM INVADES THE SPLENIC CAPSULE, AND FOCALLY INTO THE UNDERLYING PARENCHYMA.
- C. NO PERINEURAL INVASION IS IDENTIFIED.
- D. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. RESECTION MARGINS ARE FREE OF NEOPLASM.

PART 4:

LESION, PANCREAS, BIOPSY –

- A. ADIPOSE TISSUE WITH METASTATIC RENAL CELL CARCINOMA, WITH EXTENSIVE SARCOMATOID DIFFERENTIATION.
- B. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- C. NO PANCREATIC TISSUE IS IDENTIFIED.
- D. THE NEOPLASM EXTENDS TO THE RESECTION MARGINS.
- E. NO EVIDENCE OF NEOPLASIA IN 4 (0/4) LYMPH NODES.

Source: NCI Genomic Data Commons file 7bf861d5-cb31-4ded-9bff-d52a955db5ac (TCGA-B0-4688.125B79D9-4D77-4AE4-BFA8-F42798448B82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).